Somatic mutation profile of tumor specimen MP2PRT-PATFNA-TMP1-A (aliquot MP2PRT-PATFNA-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATFNA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,711 days).
Specimen MP2PRT-PATFNA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2bfc18a-ac28-4c8b-ac48-be8638f7d85e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATFNA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATFNA-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4839fa60-8b85-4c26-bc78-79ce12aacbee

The open-access MAF lists 26 somatic variants for this specimen: 16 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 13, Silent 10, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1944C>A p.S648R | Missense Mutation (SNP) | VAF 174/770 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as rs1380028281, COSV65956804; called by muse, mutect2, varscan2
- C15orf40 | c.457dup p.T153Nfs*16 | Frame Shift Ins (INS) | VAF 63/138 reads (46%) | catalogued as rs751372654; called by mutect2, varscan2
- CYP27A1 | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 52/364 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199638075, COSV51468131; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FSIP2 | c.10097C>T p.S3366F | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs917017719; called by muse, mutect2
- KRAS | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 153/353 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55561078, COSV55580549, COSV55715402; called by muse, mutect2, varscan2
- OGDHL | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 44/440 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs375897263, COSV104427167, COSV65101796; called by muse, mutect2
- SLC6A4 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 66/562 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as rs746829911, COSV99911643; called by muse, mutect2, varscan2
- SSC4D | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 198/926 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV51881134; called by muse, mutect2, varscan2
- VCAN | c.1742C>T p.T581M | Missense Mutation (SNP) | VAF 180/343 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs540758500, COSV54115974; called by muse, mutect2, varscan2
- EFHB | c.2434G>C p.E812Q | Missense Mutation (SNP) | VAF 53/387 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ETV6 | c.446_449delinsCT p.H149Pfs*4 | Frame Shift Del (DEL) | VAF 89/336 reads (26%) | called by pindel, varscan2*
- FGD5 | c.2113C>A p.Q705K | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- HAUS7 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 182/1224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAX5 | c.784_785insGCCCCTCTGA p.T262Sfs*30 | Frame Shift Ins (INS) | VAF 45/345 reads (13%) | called by mutect2, pindel
- PLEKHG6 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 115/500 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SEMA4G | c.843G>T p.Q281H | Missense Mutation (SNP) | VAF 61/462 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHST1 | c.828C>T p.C276= | Silent (SNP) | VAF 230/520 reads (44%) | catalogued as COSV57321601; called by muse, mutect2, varscan2
- CYB5D2 | c.438G>A p.P146= | Silent (SNP) | VAF 314/543 reads (58%) | catalogued as rs775221871; called by muse, mutect2, varscan2
- EIF4G1 | c.1404A>G p.A468= (on ENST00000346169 / NM_198241.3; = p.A272= on NM_004953.5) | Silent (SNP) | VAF 151/440 reads (34%) | called by muse, mutect2, varscan2
- HAUS7 | c.783C>T p.I261= | Silent (SNP) | VAF 162/1096 reads (15%) | catalogued as rs989113696; called by muse, mutect2
- MMP12 | c.285C>T p.P95= | Silent (SNP) | VAF 100/270 reads (37%) | catalogued as rs782209734, COSV100404967; called by muse, mutect2, varscan2
- PCDHA9 | c.2232G>A p.A744= | Silent (SNP) | VAF 57/618 reads (9%) | catalogued as COSV65327272, COSV65329726; called by muse, mutect2
- SPATA31A1 | c.2697G>A p.P899= | Silent (SNP) | VAF 28/128 reads (22%) | catalogued as rs1204832079; called by mutect2, varscan2
- TCOF1 | c.2925C>T p.P975= (on ENST00000377797 / NM_001135243.1; = p.P898= on NM_000356.4) | Silent (SNP) | VAF 56/608 reads (9%) | catalogued as rs747824448, COSV60352435; called by muse, mutect2
- VWF | c.8175C>T p.N2725= | Silent (SNP) | VAF 62/315 reads (20%) | catalogued as rs759147832, COSV54618520; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZNF521 | c.1158C>T p.A386= | Silent (SNP) | VAF 180/589 reads (31%) | catalogued as rs772847976; called by muse, mutect2, varscan2
